Gene-level copy-number profile of tumor specimen TCGA-AR-A1AQ-01A from TCGA case TCGA-AR-A1AQ, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 49.6 years (18,109 days).
Specimen TCGA-AR-A1AQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.ffbdf887-0c9a-40c0-971a-61eb2bb70e2a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AR-A1AQ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5db95b29-e647-40e4-bb70-8c4659d0312c

Most common (modal) total copy number across autosomal genes: 1 — below the diploid value of 2.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 29,567; copy number 2: 24,379; copy number 3: 4,535; copy number 4: 762; copy number 5: 146; copy number 6: 320; copy number 7: 77; copy number 8: 11; copy number 10: 13; copy number 12: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AR-A1AQ-01A-11D-A12N-01): tumor purity 0.46, ploidy 1.71, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:41,246,599–41,962,130, 2 genes (within-gene range 0–1): ULK4, AC099537.1.

Amplified relative to the modal value (total copy number ≥ 3, i.e. more than twice the modal value of 1; autosomes only): 5,865 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:65,792,514–104,226,678, 569 genes, copy number 3 (within-gene range 2–3) (broad region; genes not listed).
- chr1:143,343,180–156,705,816, 625 genes, copy number 3–4 (broad region; genes not listed).
- chr2:209,353,977–210,679,107, 18 genes, copy number 3: AC016743.1, MAP2, RNA5SP118, UNC80, SNAI1P1, RPE, KANSL1L, AC007038.1, KANSL1L-AS1, RPL6P6, AC006994.1, ACADL, Y_RNA, MYL1, LANCL1-AS1, LANCL1, CPS1, CPS1-IT1.
- chr6:36,672,838–60,546,660, 432 genes, copy number 3–5 (within-gene range 1–5) (broad region; genes not listed).
- chr8:8,933,721–145,066,685, 2,267 genes, copy number 3–5 (broad region; genes not listed).
- chr10:44,712–38,783,108, 673 genes, copy number 3–10 (broad region; genes not listed).
- chr10:77,313,941–83,314,475, 102 genes, copy number 3–12 (broad region; genes not listed).
- chr10:93,284,004–94,855,547, 31 genes, copy number 5–8 (within-gene range 2–8): RPL17P34, MYOF, CEP55, RNA5SP323, FFAR4, RBP4, PDE6C, FRA10AC1, LGI1, AL157396.1, AL358154.1, RAB11AP1, SLC35G1, PIPSL, PLCE1, PLCE1-AS2, AL139118.1, HDAC1P1, RNU6-657P, AL389885.1, PLCE1-AS1, AL139124.1, NOC3L, TBC1D12, HELLS, AL138759.1, CTBP2P2, CYP2C18, AL583836.1, CYP2C19, MTND4P19.
- chr16:4,180,117–4,882,401, 43 genes, copy number 3 (within-gene range 1–3): AC009171.2, SRL, LINC01569, TFAP4, GLIS2, GLIS2-AS1, PAM16, AC012676.1, CORO7-PAM16, AC012676.5, CORO7, VASN, DNAJA3, AC012676.3, AC012676.4, AC012676.2, NMRAL1, HMOX2, CDIP1, AC023830.3, C16orf96, AC023830.2, SUB1P3, UBALD1, MGRN1, RN7SL850P, AC023830.1, Metazoa_SRP, MIR6769A, NUDT16L1, ANKS3, AC020663.1, C16orf71, ZNF500, Metazoa_SRP, SEPTIN12, AC020663.4, SMIM22, AC020663.2, ROGDI, GLYR1, AC020663.3, UBN1.
- chr17:67,377,281–69,553,865, 62 genes, copy number 3 (within-gene range 2–3) (broad region; genes not listed).
- chr18:47,390–15,330,282, 376 genes, copy number 3 (broad region; genes not listed).
- chr18:39,206,917–39,800,322, 1 gene, copy number 3 (within-gene range 2–3): MIR924HG.
- chr18:39,334,872–80,247,514, 590 genes, copy number 3–4 (broad region; genes not listed).
- chr19:45,933,734–47,005,077, 56 genes, copy number 3 (within-gene range 1–3): NOVA2, CCDC61, MIR769, PGLYRP1, AC007785.3, IGFL4, AC007785.1, AC007785.2, IGFL3, TGIF1P1, IGFL2, AC006262.2, IGFL2-AS1, IGFL1P1, AC006262.1, RPL12P41, AC006262.3, IGFL1, AC006262.4, IGFL1P2, HIF3A, RNU6-924P, AC007193.2, PPP5C, AC007193.1, AC007193.3, CCDC8, PNMA8C, PNMA8A, PPP5D1, PNMA8B, AC011484.1, AC011551.1, GAPDHP38, CALM3, AC093503.1, PTGIR, GNG8, AC093503.2, DACT3, DACT3-AS1, PRKD2, RN7SL364P, MIR320E, STRN4, AC008635.1, Y_RNA, FKRP, SLC1A5, AC008622.2, AC008622.3, HNRNPMP2, AC008622.1, AP2S1, ARHGAP35, AC008895.1.
- chr19:54,617,158–54,713,453, 10 genes, copy number 3: LILRB1, LILRB1-AS1, LILRB4, MIR8061, VN1R105P, AC245036.3, AC243962.1, LILRP1, AC245128.2, LILRP2.
- chr20:9,986,088–10,368,776, 10 genes, copy number 3 (within-gene range 2–3): PARAL1, ANKEF1, SNAP25-AS1, Metazoa_SRP, AL354824.1, AL354824.2, SNAP25, AL023913.1, HIGD1AP15, RPL23AP6.

Autosomal genes at a single copy (total copy number 1): 27,146. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
